Somatic mutation profile of tumor specimen TCGA-AN-A0FZ-01A (aliquot TCGA-AN-A0FZ-01A-11W-A050-09) from TCGA case TCGA-AN-A0FZ, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 45.3 years (16,533 days).
Specimen TCGA-AN-A0FZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3d5f9c14-78b4-428f-a1c1-1d39e27be87f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AN-A0FZ-10A (Blood Derived Normal), aliquot TCGA-AN-A0FZ-10A-01W-A055-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1d93b71d-389a-4e5e-bdb2-ef619ac63cea

The open-access MAF lists 72 somatic variants for this specimen: 58 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 13, Nonsense Mutation 2, Intron 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRG5 | c.397T>A p.C133S | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61084647; called by muse, mutect2, varscan2
- ADGRL3 | c.2362G>A p.G788S (on ENST00000506720 / NM_001322402.2; = p.G720S on NM_015236.6) | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT tolerated (0.61); PolyPhen benign (0.158); catalogued as COSV101547408; called by muse, mutect2
- AP4E1 | c.847C>T p.L283F | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.463); catalogued as rs780730473, COSV55920357; called by muse, mutect2, varscan2
- APTX | c.103A>T p.I35F | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100541454; called by muse, mutect2
- ATG2B | c.4369G>A p.E1457K | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs1357232189, COSV55892204; called by muse, mutect2, varscan2
- CFP | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV55950478; called by muse, mutect2, varscan2
- COG5 | c.1592A>G p.D531G | Missense Mutation (SNP) | VAF 150/287 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.134); catalogued as COSV51765231; called by muse, mutect2, varscan2
- COMP | c.1117G>A p.D373N | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.047); catalogued as rs757207641, COSV55876606; called by muse, mutect2, varscan2
- CUL7 | c.5042G>A p.R1681Q | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.846); catalogued as rs1163584400, COSV54822233; called by muse, mutect2, varscan2
- DDX53 | c.21G>T p.E7D | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.173); catalogued as COSV100029120, COSV60070129; called by muse, mutect2, varscan2
- DMBT1 | c.5049G>T p.W1683C (on ENST00000338354 / NM_001377530.1; = p.W926C on NM_004406.3) | Missense Mutation (SNP) | VAF 29/194 reads (15%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as COSV57563510; called by muse, mutect2, varscan2
- DNAH10 | c.6385G>A p.V2129I (on ENST00000409039; = p.V2068I on NM_207437.3) | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.345); catalogued as rs557513283, COSV68992263; called by muse, mutect2, varscan2
- ECE1 | c.1846C>A p.Q616K | Missense Mutation (SNP) | VAF 6/130 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.113); catalogued as COSV51666715, COSV99941676; called by muse, mutect2
- EVPL | c.4354C>T p.R1452W | Missense Mutation (SNP) | VAF 72/130 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.727); catalogued as rs774293924, COSV56916416; called by muse, mutect2, varscan2
- FAT3 | c.12433G>A p.A4145T | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.292); catalogued as rs553837148, COSV53177102; called by muse, mutect2, varscan2
- FCRL5 | c.2106G>T p.K702N | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT tolerated (0.7); PolyPhen benign (0.006); catalogued as COSV62511257; called by muse, mutect2
- GATA3 | c.1003dup p.D335Gfs*17 | Frame Shift Ins (INS) | VAF 82/324 reads (25%) | catalogued as COSV60519609; called by mutect2, pindel, varscan2
- GLIS2 | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1369177210, COSV52111321; called by muse, mutect2
- GPR149 | c.1110G>T p.L370F | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.11); catalogued as COSV101078772; called by muse, mutect2
- HMCN1 | c.9101C>A p.T3034N | Missense Mutation (SNP) | VAF 35/361 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99636486; called by muse, mutect2, varscan2
- ISL1 | c.997T>C p.S333P | Missense Mutation (SNP) | VAF 38/202 reads (19%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.976); catalogued as COSV57935871; called by muse, mutect2, varscan2
- ITGA4 | c.2881C>T p.H961Y | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100184233; called by muse, mutect2
- KCNV1 | c.1301G>T p.C434F | Missense Mutation (SNP) | VAF 19/294 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV99819466; called by muse, mutect2
- KRT6B | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs374275504, COSV99361058; called by muse, mutect2, varscan2
- KRTAP19-6 | c.55G>A p.G19S | Missense Mutation (SNP) | VAF 64/296 reads (22%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.054); catalogued as COSV61844270, COSV61844390; called by muse, mutect2, varscan2
- LAMA2 | c.6062G>A p.G2021E | Missense Mutation (SNP) | VAF 24/244 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV101370878; called by muse, mutect2
- LZTS1 | c.106C>T p.R36W | Missense Mutation (SNP) | VAF 29/44 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs201531859, COSV56116032; called by muse, mutect2, varscan2
- MAST4 | c.2599G>A p.D867N (on ENST00000403625 / NM_001164664.2; = p.D678N on NM_015183.3) | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55142983; called by muse, mutect2, varscan2
- MGAT4B | c.1576C>T p.R526C | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs1381451708, COSV52979888; called by muse, mutect2, varscan2
- MYBBP1A | c.2288T>C p.V763A | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.946); catalogued as COSV54604762; called by muse, mutect2, varscan2
- MYBPC2 | c.1866C>A p.N622K | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs1284579421, COSV63100129; called by muse, mutect2, varscan2
- MYCBP2 | c.5114C>G p.S1705C (on ENST00000357337; = p.S1743C on NM_015057.5) | Missense Mutation (SNP) | VAF 25/248 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100632067; called by muse, mutect2, varscan2
- N4BP2 | c.935C>T p.T312I | Missense Mutation (SNP) | VAF 50/168 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV54707200; called by muse, mutect2, varscan2
- NAV3 | c.5542G>A p.E1848K (on ENST00000397909 / NM_001024383.2; = p.E1826K on NM_014903.6) | Missense Mutation (SNP) | VAF 30/632 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99896126; called by muse, mutect2
- NELL2 | c.1102C>T p.L368F | Missense Mutation (SNP) | VAF 21/190 reads (11%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV61579970; called by muse, mutect2, varscan2
- OR5D18 | c.262G>T p.V88F | Missense Mutation (SNP) | VAF 71/381 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as COSV61738714; called by muse, mutect2, varscan2
- OR6C6 | c.334C>T p.L112F | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.029); catalogued as COSV64456315; called by muse, mutect2, varscan2
- PGM1 | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT tolerated (0.58); PolyPhen benign (0.105); catalogued as rs748304901, COSV64301641; called by muse, mutect2, varscan2
- PRKCA | c.1621G>A p.E541K | Missense Mutation (SNP) | VAF 6/147 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.397); catalogued as COSV101151268; called by muse, mutect2
- PSMD4 | c.1099G>A p.G367S | Missense Mutation (SNP) | VAF 193/357 reads (54%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs770584632, COSV64393716; called by muse, mutect2, varscan2
- PTPRD | c.1720G>T p.G574* | Nonsense Mutation (SNP) | VAF 90/616 reads (15%) | catalogued as COSV61974072, COSV61983025; called by muse, mutect2, varscan2
- SEPHS2 | c.1210G>A p.V404I | Missense Mutation (SNP) | VAF 90/191 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.062); catalogued as rs770036742, COSV72100828; called by muse, mutect2, varscan2
- SGPL1 | c.147G>A p.W49* | Nonsense Mutation (SNP) | VAF 46/242 reads (19%) | catalogued as COSV54737888; called by muse, mutect2, varscan2
- SH3TC1 | c.825G>T p.L275F | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99795356; called by muse, mutect2
- SLCO3A1 | c.1408C>T p.P470S | Missense Mutation (SNP) | VAF 38/326 reads (12%) | SIFT tolerated (0.73); PolyPhen benign (0.006); catalogued as COSV59237795; called by muse, mutect2, varscan2
- SPATA5 | c.430A>G p.M144V | Missense Mutation (SNP) | VAF 17/192 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99916493; called by muse, mutect2
- TBCE | c.397G>A p.G133S (on ENST00000366601; = p.G196S on NM_003193.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/356 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.036); catalogued as rs1409065511, COSV100783270; called by muse, mutect2
- TFRC | c.1511C>T p.T504M | Missense Mutation (SNP) | VAF 68/266 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.055); catalogued as rs769366579, COSV64055014; called by muse, mutect2, varscan2
- TMC2 | c.1925A>G p.N642S | Missense Mutation (SNP) | VAF 113/299 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.323); catalogued as COSV62658674; called by muse, mutect2, varscan2
- TMEM159 | c.97G>A p.V33M | Missense Mutation (SNP) | VAF 24/580 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.26); catalogued as rs780090255, COSV99238899; called by muse, mutect2
- TMEM40 | c.247G>A p.G83R | Missense Mutation (SNP) | VAF 20/288 reads (7%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.001); catalogued as rs758550120, COSV99277376; called by muse, mutect2
- TRHDE | c.2593G>C p.D865H | Missense Mutation (SNP) | VAF 28/660 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99672769; called by muse, mutect2
- TRIM41 | c.85G>T p.D29Y | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100163548; called by muse, mutect2
- TSPOAP1 | c.1042C>T p.R348W | Missense Mutation (SNP) | VAF 9/225 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1567850059, COSV99272952; called by muse, mutect2
- VNN2 | c.1094T>A p.L365H | Missense Mutation (SNP) | VAF 115/364 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58474504; called by muse, mutect2, varscan2
- ZNF658 | c.1973A>G p.Y658C | Missense Mutation (SNP) | VAF 30/176 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs374278799; called by muse, mutect2, varscan2
- ZNF680 | c.490C>A p.H164N | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.065); catalogued as COSV59018307; called by muse, mutect2, varscan2
- CDKN1B | c.152_162del p.D51Gfs*70 | Frame Shift Del (DEL) | VAF 19/41 reads (46%) | called by mutect2, pindel, varscan2
- ANKRD24 | c.1065G>A p.P355= | Silent (SNP) | VAF 51/333 reads (15%) | catalogued as rs769178978, COSV53675955; called by muse, mutect2, varscan2
- CEMIP2 | c.1422G>A p.E474= | Silent (SNP) | VAF 16/242 reads (7%) | catalogued as COSV100987523; called by muse, mutect2
- DNAH11 | c.13488G>A p.L4496= | Silent (SNP) | VAF 44/742 reads (6%) | catalogued as COSV100181105; called by muse, mutect2
- DOCK1 | c.2532C>T p.I844= | Silent (SNP) | VAF 11/85 reads (13%) | catalogued as rs35102871; called by muse, mutect2, varscan2
- EPS15L1 | c.1608G>A p.T536= | Silent (SNP) | VAF 13/106 reads (12%) | catalogued as rs767571837, COSV50171460; called by muse, mutect2, varscan2
- GRSF1 | c.843G>T p.V281= | Silent (SNP) | VAF 22/208 reads (11%) | catalogued as COSV54657300; called by muse, mutect2, varscan2
- KMT5B | c.1581G>T p.S527= | Silent (SNP) | VAF 13/197 reads (7%) | catalogued as COSV100430484; called by muse, mutect2
- OS9 | c.1788C>T p.V596= | Silent (SNP) | VAF 37/424 reads (9%) | catalogued as COSV99224375; called by muse, mutect2
- OS9 | c.1875C>T p.I625= | Silent (SNP) | VAF 36/312 reads (12%) | catalogued as COSV57732285; called by muse, mutect2, varscan2
- SLC32A1 | c.615G>A p.V205= | Silent (SNP) | VAF 14/87 reads (16%) | catalogued as COSV54148447; called by muse, mutect2, varscan2
- SULT1C2 | c.102C>T p.S34= | Silent (SNP) | VAF 9/292 reads (3%) | catalogued as rs1370689059, COSV99265455; called by muse, mutect2
- TRIB2 | c.708C>T p.D236= | Silent (SNP) | VAF 42/105 reads (40%) | catalogued as rs767201489, COSV50231475; called by muse, mutect2, varscan2
- XRCC2 | c.234C>T p.V78= | Silent (SNP) | VAF 13/137 reads (9%) | catalogued as rs1021845968, COSV100831706; called by muse, mutect2
- NBPF11 | c.-548-2766C>A | Intron (SNP) | VAF 2/16 reads (13%) | called by muse, mutect2
